Surgical pathology report (de-identified scan), TCGA case TCGA-QQ-A5V9, project TCGA-SARC (Sarcoma), tissue source site Roswell Park, specimen TCGA-QQ-A5V9-01A (Primary Tumor).

[page 1 of 2]
TSS DeID:
Surgery Date:

SPECIMENS:

FS1 RT RETROPERITONEAL TUMOR/RT NEPHRECTOMY
LT LOBE LIVER
RT LOBE LIVER

FINAL DIAGNOSIS:

1. RIGHT RETROPERITONEAL TUMOR, RIGHT NEPHRECTOMY:
-MALIGNANT FIBROUS HISTIOCYTOMA (PLEOMORPHIC TYPE) OF SOFT TISSUE OF RIGHT RETROPERITONEUM.
-Size of tumor: 17.0x11.0x5.5 cm.
-Margins of resection - free of tumor
-FOCAL INTERSTITIAL PYELONEPHRITIS OF RIGHT KIDNEY
-RIGHT URETER: No specific pathologic changes; NO TUMOR seen
-Portion of LIVER: CONGESTION; NO TUMOR seen
-RIGHT ADRENAL GLAND: NO TUMOR seen
2. LEFT LOBE OF LIVER: LIVER TISSUE, no specific pathologic changes; NO TUMOR seen
3. RIGHT LOBE OF LIVER: Fragment of LIVER TISSUE; NO TUMOR seen; see note

DIAGNOSIS COMMENT:

In #1, pleomorphic bizarre giant tumor cells best seen in Slides #1T3, T9, and T10. Coarse calcification in Slide FS1B.

There's extension of tumor to perinephric fat, but kidney is free of tumor involvement. Nearest inked margins of resection are free of tumor.

Immunohistochemistry stains for S-100, NSE, and CD-68 were negative.

GROSS DESCRIPTION:

The specimen consists of three parts labelled with the name of patient and the number of the specimen.

1.- RADICAL RESECTION RT RETROPERITONEAL TUMOR/RT NEPHRECTOMY

Received is an en bloc resected specimen comprising of a huge tumor with the adherent kidney and the perinephric fat. The overall dimensions of the specimen are 27x9.0 to 14.0x7cm. It weighs 1300gm. The tumor seems encapsulated and measures 17x11x5.5cm. The cut surface shows a coarsely lobulated with firm and fish fleshy parenchyma and with creamy yellow specks. It is adherent to the perinephric fat but not the kidney per se. The kidney has a fetal lobulations. The capsule of the kidney strips off with difficulty and the kidney measures 11x6x3.5cm. Its surface is coarsely granular. The ureter measures 7.5cm. from renal pelvis and found patent and free from extrinsic compression. The kidney has a distinct cortical medullary border with hyperemic cortex. The adrenal gland measures 3x1x2cm. The small portion of attached liver is identified which measures 3x1x0.9cm. The sections are submitted as follows:

AD1 to AD3: from the adrenal

K1 and K2: kidney

RP: renal pelvis

D: distal ureter

TPCP1 and TPCP2: tumor with capsule

PF: perinephric fat

T1 to T10: tumor (T9 section is taken from the tumor with the diaphragm)

LV: liver

FS1A and FS1B: frozen on the tumor

2. LT LOBE LIVER

path ICD-O-3
Histocytoma, fibrous, malignant-
pleomorphic type 8836/3
QCF Sarcoma, pleomorphic, undifferentiated
8805/3
path
Site Connective, subcutaneous and
other soft tissues of shoulder
C49.1
QCF Connective, subcutaneous and
other soft tissues of
extremities C49.9
QW 4/11/13

[page 2 of 2]
Received is an elongated, thin filamentous tan white tissue measuring 1.3cm. in maximum dimensions. It is submitted in toto in one cassette labelled 1.

3. RT LOBE LIVER

Received is a tan tissue measuring 0.4cm. in maximum dimension. It is submitted in one cassette labelled 1.

Source: NCI Genomic Data Commons file d56731de-648d-46d1-87db-2eb14f7508ad (TCGA-QQ-A5V9.71EA84E3-A8C9-4DD6-9864-971CD3BC6B98.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).